Somatic mutation profile of tumor specimen C3N-03180-02 (aliquot CPT0206450009) from CPTAC case C3N-03180, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.1 years (19,399 days).
Specimen C3N-03180-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e681c7e4-e0c2-41ef-95d6-f5b4a08643d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03180-71 (Blood Derived Normal), aliquot CPT0206500002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7d426a2-5d38-4c3f-9eb1-e5ff855b97b6

The open-access MAF lists 36 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 7, Intron 4, Nonsense Mutation 2, 3'UTR 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 852/1682 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CCDC168 | c.16228C>T p.R5410* | Nonsense Mutation (SNP) | VAF 11/99 reads (11%) | catalogued as rs777750006; called by muse, mutect2, varscan2
- CEACAM7 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 54/468 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs539835752; called by muse, mutect2, varscan2
- COL6A5 | c.4024A>G p.T1342A | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV55214914; called by muse, mutect2
- CPE | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); catalogued as rs144727363; called by muse, mutect2
- ENAM | c.2569C>A p.P857T | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV68536285; called by muse, mutect2
- FCGBP | c.11227C>T p.R3743W | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.809); catalogued as rs372154389; called by muse, mutect2
- HCN1 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV57537310, COSV57542378; called by muse, mutect2
- INTS4 | c.205G>C p.V69L | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs144227709; called by muse, mutect2
- NLRP7 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 60/720 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs777760472; called by muse, mutect2
- TNIK | c.1345C>T p.R449* | Nonsense Mutation (SNP) | VAF 16/217 reads (7%) | catalogued as COSV52683181, COSV52692815; called by muse, mutect2
- TRPV6 | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777616496, COSV63892749; called by muse, mutect2
- ZPBP | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0.019); catalogued as rs148913753; called by muse, mutect2
- ARAF | c.459-2A>G p.X153_splice | Splice Site (SNP) | VAF 42/120 reads (35%) | called by muse, mutect2, varscan2
- CSPP1 | c.3150G>C p.Q1050H (on ENST00000676605; = p.Q1009H on NM_024790.6) | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- INVS | c.56A>C p.H19P | Missense Mutation (SNP) | VAF 29/439 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- KPTN | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 23/469 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2
- MYCBPAP | c.935A>G p.D312G | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.121); called by muse, mutect2
- PLB1 | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 26/307 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2
- PPP6R3 | c.1448A>C p.Q483P (on ENST00000393800 / NM_001352375.2; = p.Q432P on NM_018312.5) | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- TERT | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 21/325 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- TRPM1 | c.445G>C p.G149R | Missense Mutation (SNP) | VAF 42/599 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- VSTM4 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ATP6V1B2 | c.39C>T p.A13= | Silent (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- C1QTNF8 | c.228C>T p.G76= | Silent (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- C9 | c.237C>T p.T79= | Silent (SNP) | VAF 30/322 reads (9%) | catalogued as rs754596142; called by muse, mutect2
- CD177 | c.660C>T p.H220= | Silent (SNP) | VAF 17/262 reads (6%) | catalogued as rs369605415; called by muse, mutect2
- LDLRAD1 | c.582C>T p.S194= | Silent (SNP) | VAF 20/212 reads (9%) | catalogued as rs929359424; called by muse, mutect2
- NEUROD6 | c.375T>C p.S125= | Silent (SNP) | VAF 33/375 reads (9%) | called by muse, mutect2
- SMR3B | c.102G>A p.P34= | Silent (SNP) | VAF 18/232 reads (8%) | catalogued as rs187778726, COSV59229652; called by muse, mutect2
- GPR68 | c.-129-9251G>A | Intron (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- IL13RA1 | c.1009+3396G>A | Intron (SNP) | VAF 55/213 reads (26%) | catalogued as rs961450076, COSV100861497; called by muse, mutect2, varscan2
- NOS1AP | c.939+3695C>T | Intron (SNP) | VAF 29/289 reads (10%) | catalogued as COSV100722721; called by muse, mutect2, varscan2
- SLC6A10P | n.3203G>A | RNA (SNP) | VAF 30/504 reads (6%) | called by muse, mutect2
- ST3GAL5 | c.319-269T>G | Intron (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- SULF1 | c.*729A>T | 3'UTR (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
